Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A3BG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A3BG-01A (Primary Tumor).

[page 1 of 3]
Sex: Female
D.O.B.:
MRN #
Ref Phy:

Collected
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Uterine contents, removal:
High-grade adenocarcinoma with extensive necrosis - see comment.
- B. Left ovary and fallopian tube, salpingo-oophorectomy:
Left ovary -
Benign ovary with serosal fibrous adhesions.
No neoplastic process is identified.
Left fallopian tube -
Benign fallopian tube with no neoplasm identified.
- C. Right ovary and fallopian tube, salpingo-oophorectomy:
Right ovary -
Benign ovary with serosal fibrous adhesions.
No neoplasm identified.
Right fallopian tube -
Acute salpingitis.
- D. Uterus, hysterectomy:
High-grade endometrial adenocarcinoma
Histologic type: mixed endometrioid adenocarcinoma and papillary serous carcinoma - see comment.
Histologic grade: Grade 3 (high grade).
Size: At least 8 cm in greatest dimension with additional material in specimens A and F.
Myometrial invasion: Tumor invades less than one-half the thickness of the myometrium.
Greatest depth of invasion is 3 mm into an area of myometrium that is 9 mm thick.
Foci of lymphovascular space invasion present.
Surgical margin: Lesion not identified at lower uterine segment margin.
AJCC cancer staging of the endometrium: pT1aN0
- E. Cervix, excision:
Ulceration with marked acute and chronic inflammation.
No neoplasm identified.
- F. Uterine contents, removal:
High-grade adenocarcinoma with extensive necrosis.
- G. Lymph nodes, left common lower aortic, excision:
No neoplasm identified in two lymph nodes.
- H. Lymph nodes, left external iliac, excision:
No neoplasm identified in two lymph nodes.
- I. Lymph nodes, left obturator, excision:
No neoplasm identified in two lymph nodes.
- J. Lymph nodes, right lower aortic, excision:
No neoplasm identified in two lymph nodes.
- K. Lymph nodes, right external iliac, excision:
No neoplasm identified in three lymph nodes.
- L. Lymph nodes, right external iliac, excision:
No neoplasm identified in two lymph nodes.
- M. Lymph nodes, right obturator, excision:
No neoplasm identified in four lymph nodes.

103-0-3 8380/3
adenocarcinoma, endometrioid and
papillary serous 8460/3 - code to highest 8460/3
Site: Endometrium C54.1 lw 10/25/11

[page 2 of 3]
N. Omentum, omentectomy:
No neoplasm identified.

Electronic Signature:

COMMENTS:

There is a high grade adenocarcinoma involving the uterus which has predominantly an endometrioid pattern. There are areas that have an appearance of papillary carcinoma, and these foci stain positively for p53. There also are solid sheets of highly atypical neoplastic cells. There is an area lymph vascular space invasion.

Selected slides reviewed by

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Pelvic mass.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Uterine contents - FS.
- B. Left tube and ovary.
- C. Right tube and ovary.
- D. Uterus.
- E. Cervix.
- F. Uterine contents.
- G. Left common lower aortic.
- H. Left external iliac.
- I. Left obturator
- J. Right lower aortic and common lymph node.
- K. Right external iliac suspicious node.
- L. Right external iliac.
- M. Right obturator.
- N. Omentum.

SPECIMEN DATA

GROSS DESCRIPTION:

A. First container A is labeled with the patient's name #1. The specimen consists of an aggregate of yellow-gray shaggy tissue fragments measuring in aggregate by 16.5 x 15.4 cm, weighing 422 grams. A representative section from the specimen was examined at the time of surgery. Received with the specimen is a single yellow cassette labeled as follows: FS in block 1; additional sections from the specimen in blocks 2-9.

B. Second container B labeled #2/ovary. The specimen consists of an ovary with an attached fallopian tube. The ovary measures 3.5 x 0.5 x 0.5 cm. The surface is yellow to gray-tan. The cut surface is gray-tan and reveals a corpus albicans up to 0.6 cm. There is no lesions grossly identified. The attached fallopian tube is 5.5 cm. in length and 0.5 cm. in diameter. The surface is gray to brown-tan. Sectioning there is no mature lesions identified. The fallopian tube appears grossly unremarkable. Representative sections are submitted in cassette labeled as follows: ovary in total in blocks 1 and 2; representative fallopian tube in block 3.

C. Third container C is labeled with the patient's name right tube/ovary and consists of an ovary with attached fallopian tube. The ovary measures 2.2 x 1.5 x 0.5 cm. The surface is yellow to gray-tan. Sectioning there is corpus albicans identified measuring up to 0.5 cm. There is lesions grossly identified. The fallopian tube measures 6 cm. in length and 0.5 cm. in diameter. The surface is gray to brown-tan. On sectioning there is no mature lesions identified within the lumen. The fallopian tube appears grossly unremarkable. Representative sections are submitted in cassettes labeled as follows: ovary in total in blocks 1-2; representative fallopian tube in block 3.

D. Fourth container D is labeled with the patient's uterus. The specimen consists of a partially bisected supracervical hysterectomy specimen measuring 13 x 7 x 5.5 cm, and weighs 193 grams. The serosal surface of the uterus is gray to brown-tan with slight hemorrhage and adhesions. The serosal surface has been inked. Endometrial cavity measures 10 x 6.5 cm, and is lined by a brown-tan shaggy friable mass involving the entire uterine cavity that measures 8 x 5.5 cm, and comes within 2 cm. of the resected margin at the lower uterine segment. The mass extends into the underlying myometrium approximately 0.4 cm. into a 0.8 cm. myometrium. The myometrium is gray-tan trabecular. There is no lesions grossly identified. Received with the specimen are two cassettes, one green, one yellow labeled (with the green additionally labeled - 17 and the blue additionally black 18. Representative sections are submitted in cassettes labeled is follows: full thickness sections from the mass in blocks 1 through 6; resected margin at the area of the lower uterine segment in block 7; left parametrium in block 8; right parametrium in block 9.

E. The fifth container E is labeled the patient's name . The specimen consists of cervical tissue that measures 2.2 cm. in length

[page 3 of 3]
and 3 cm. in diameter and has a 2 cm. round patent os. The ectocervical mucosa is gray-tan to brown-tan with hemorrhage. Sectioning there is no lesions grossly identified. Representative sections are submitted in four cassettes labeled

F. The sixth container F is labeled the patient's name ; uterine contents. The specimen consists of an aggregate of gray to red-tan shaggy soft tissue fragments measuring in aggregate 15 x 2 x 4.5 cm. and weighs 312 grams. Representative sections are submitted in two cassettes labeled

G. The seventh container G is labeled the patient's name ; left common aortic. The specimen consists of a portion of fibroadipose tissue measuring 3 x 2 x 1 cm. Sectioning reveals three probable lymph nodes that measure from 0.2 to 0.8 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: two probable nodes in block 1; one probable node in block 2.

H. The eighth container H is labeled the patient's name ; left external iliac. The specimen consists of a portion of fibroadipose tissue measuring 5 x 4.5 x 1.2 cm. Sectioning reveals two probable lymph nodes that measure from 0.6 to 0.9 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node block 1; one probable node bisected in block 2.

I. The ninth container I is labeled with the patient's name ; left obturator. The specimen consists of a portion of fibroadipose tissue 4.5 x 4 x 1 cm. Sectioning reveals two probable lymph nodes that measure 1.1 and 1.5 cm. in greatest dimension. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node bisected in block 1; one probable node bisected in block 2.

J. The tenth container J is labeled he specimen consists of a portion of fibroadipose tissue measuring 4.5 x 1.5 x 1 cm. Sectioning reveals two probable lymph nodes that measures 0.9 and 1.5 cm. in greatest dimension. The lymph nodes are entirely submitted in three cassettes labeled as follows: one probable node bisected in block 1; one probable node bisected in blocks 2-3.

K. The eleventh container K is labeled with the patient's name #11. The specimen consists of a portion of fibroadipose tissue measuring 3 x 2.5 x 0.5 cm. Sectioning reveals three probable lymph nodes that measure from 0.5 to 1.5 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node bisected in block 1; two probable nodes in block 2.

L. The twelfth container L is labeled #12 and consists of a portion of fibroadipose tissue, 5 x 3 x 0.5 cm. Sectioning reveals two probable lymph nodes that measure 0.7 and 1.8 cm. in greatest dimension. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable lymph node bisected in block 1; one probable lymph node bisected in blocks 2 and 3.

M. The thirteenth container M is labeled and consists of a portion of fibroadipose tissue measuring 6 x 4 x 1 cm. Sectioning reveals four probable lymph nodes that measure from 0.5 to 1.5 cm. The lymph nodes are entirely submitted in cassettes as follows: two probable nodes in block 1; one probable node bisected in blocks 2 and 3; one probable lymph node bisected in block 4.

N. The fourteenth container N is labeled The specimen consists of a portion of yellow-tan lobular fibroadipose omentum tissue measuring 34 x 5 x 2 cm. On sectioning there no nodules grossly identified. Representative sections are submitted in four cassettes labeled

INTRA-OPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS: Adenocarcinoma, favor high-grade per D

Source: NCI Genomic Data Commons file 4e4ab23e-d389-463f-9c64-248b6aef51e2 (TCGA-AJ-A3BG.3D42566F-92B2-4530-BF6A-624DA6E979B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).